Gene-level copy-number profile of tumor specimen TCGA-Q9-A6FU-01A from TCGA case TCGA-Q9-A6FU, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 57.8 years (21,108 days).
Specimen TCGA-Q9-A6FU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.920b0ec8-2aec-44ea-9be9-d222682fb004.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-Q9-A6FU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bfd4f349-3988-4a90-a0a8-75ea87977386

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 15,331; copy number 2: 39,731; copy number 3: 2,552; copy number 4: 696; copy number 5: 1,187; copy number 6: 127; copy number 7: 41; copy number 8: 23; copy number 9: 43; copy number 11: 29; copy number 15: 5; copy number 18: 5; copy number 23: 9; copy number 34: 11; copy number 55: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-Q9-A6FU-01A-11D-A31T-01): tumor purity 0.67, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr3:11,488,300–11,529,755, 2 genes: AC026185.1, AC022001.1.
- chr3:11,607,184–11,612,197, 2 genes: AC022001.2, AC022001.3.
- chr4:90,370,123–90,370,427, 1 gene: RN7SKP248.
- chr4:98,025,390–98,443,858, 5 genes: RPL5P12, DUTP8, AC019077.1, RAP1GDS1, AC058823.1.
- chr9:138,129,399–138,203,325, 5 genes: AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1.
- chr16:7,726,841–7,726,951, 1 gene: AC005774.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,483 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:132,417,502–175,810,548, 640 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:175,234,861–198,222,513, 495 genes, copy number 5 (broad region; genes not listed).
- chr4:145,757,627–149,278,123, 49 genes, copy number 8–18 (within-gene range 3–18): ZNF827, AC104791.2, AC104791.1, Y_RNA, AC108206.1, LINC01095, LSM6, AC097372.2, REELD1, AC097372.3, AC097372.1, SLC10A7, MIR7849, RNU1-44P, POU4F2, TTC29, AC092435.2, AC092435.1, AC092435.3, AC092435.4, AC097450.1, MIR548G, AC010683.1, PRMT5P1, EDNRA, AC093908.1, GTF2F2P1, LINC02507, AC093835.1, TMEM184C, PRMT9, ARHGAP10, RNA5SP165, MIR4799, RN7SL254P, AC115621.1, NR3C2, AC069272.1, AC002460.2, ASS1P8, RNA5SP166, AC108935.1, ATP5MGP4, AC093648.1, AC002460.1, RNU7-197P, AC108156.1, LINC02430, LINC02355.
- chr4:149,377,257–149,380,107, 1 gene, copy number 11: AC108168.1.
- chr5:32,522,758–34,124,528, 27 genes, copy number 5 (within-gene range 4–5): AC074134.1, SUB1, LINC02061, AC008766.1, NPR3, AC025459.1, AC010343.3, LINC02120, AC034223.1, AC034223.2, AC010343.2, AC010343.1, LINC02160, AC025472.1, AC034231.1, TARS1, TOMM40P3, AC034232.1, ADAMTS12, RNU6-923P, RXFP3, SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3.
- chr6:10,722,915–13,287,843, 39 genes, copy number 6–23 (within-gene range 1–23): TMEM14C, AL024498.1, TMEM14B, AL024498.2, RNA5SP203, MAK, GCM2, AL357497.1, SYCP2L, ELOVL2, AL121955.1, ELOVL2-AS1, SMIM13, ERVFRD-1, AL136139.1, AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP, AL022724.1, ADTRP, AL022724.3, AL022724.2, AMD1P4, AL157373.1, AL157373.2, HIVEP1, EDN1, SUMO2P12, RN7SKP293, RPL15P3, LINC02530, PHACTR1.
- chr6:19,143,695–22,654,455, 38 genes, copy number 6 (within-gene range 1–6): AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1.
- chr6:28,188,050–29,633,976, 84 genes, copy number 7–9 (within-gene range 2–9) (broad region; genes not listed).
- chr7:53,776,136–55,433,742, 26 genes, copy number 8–55: RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.
- chr11:90,869,121–92,985,066, 25 genes, copy number 5 (within-gene range 1–5): MIR1261, AP001002.3, AP001002.1, AP001002.2, OSBPL9P2, OSBPL9P3, LINC02748, AP003485.2, AP003485.1, AP002791.1, LINC02756, TUBB4BP4, AP002799.1, RPL7AP57, NDUFB11P1, FAT3, PGAM1P9, AP000722.1, RPS3AP42, AP003718.1, LINC02746, AP003171.2, SNRPGP16, AP003171.1, MTNR1B.
- chr13:112,602,828–114,337,626, 59 genes, copy number 6: AL139384.2, ATP11AUN, AL139384.1, ATP11A, ATP11A-AS1, AL356752.1, MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, C13orf46, RASA3, RASA3-IT1, CFAP97D2, AL160396.1, CDC16, MIR548AR, MIR4502, AL160396.2, UPF3A, CLCP2, CHAMP1, LINC01054.

Autosomal genes at a single copy (total copy number 1): 15,132. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
